Gene-level copy-number profile of tumor specimen C3N-00217-02 from CPTAC case C3N-00217, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 59.8 years (21,854 days).
Specimen C3N-00217-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 78552f42-56ca-4333-a3e6-1741b91364a5.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00217-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,234 have no estimate.
https://portal.gdc.cancer.gov/files/d7bb61cd-fcb9-48cf-bd2b-651f24a1caa2

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 208; copy number 2: 10,351; copy number 3: 10,965; copy number 4: 22,487; copy number 5: 5,979; copy number 6: 5,409; copy number 7: 2,248; copy number 8: 372; copy number 9: 6; copy number 10: 165; copy number 11: 31; copy number 12: 60; copy number 20: 3; copy number 21: 9; copy number 32: 49; copy number 54: 12; copy number 95: 31.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:13,844,101–13,849,109, 1 gene: AC022690.2.
- chr14:27,258,717–27,845,286, 3 genes: AL390334.1, LINC00645, MIR3171.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 366 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,675,205–150,353,233, 39 genes, copy number 10: FAM91A2P, AC243772.3, RNU1-68P, AC243772.1, FCGR1A, H2BC18, AC243772.2, H3C13, H4C14, H3C14, H2AC18, H2BC19P, H2BC20P, H2AC19, H3C15, H4C15, AC239868.1, H2BC21, H2AC20, H2AC21, BOLA1, SV2A, SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45, PLEKHO1, RN7SL480P, ANP32E, RNU2-17P, AC242988.1, CA14, APH1A, C1orf54, CIART, MRPS21, PRPF3.
- chr1:150,508,062–150,560,937, 5 genes, copy number 10 (within-gene range 7–10): ECM1, FALEC, ADAMTSL4-AS2, ADAMTSL4, MIR4257.
- chr1:150,600,851–150,629,612, 1 gene, copy number 10 (within-gene range 7–10): ENSA.
- chr1:150,646,230–152,196,699, 90 genes, copy number 10 (within-gene range 7–10) (broad region; genes not listed).
- chr1:196,774,813–196,795,407, 1 gene, copy number 12: CFHR3.
- chr6:25,061,626–25,452,263, 1 gene, copy number 9 (within-gene range 5–9): CMAHP.
- chr6:25,261,239–25,620,530, 5 genes, copy number 9 (within-gene range 5–9): AL024509.2, AL024509.1, CARMIL1, Y_RNA, RNU6-987P.
- chr6:31,195,200–31,862,905, 89 genes, copy number 10–12 (broad region; genes not listed).
- chr8:35,862,123–40,520,158, 104 genes, copy number 11–54 (broad region; genes not listed).
- chr11:68,870,664–69,926,813, 31 genes, copy number 95: LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2.

Autosomal genes at a single copy (total copy number 1): 208. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
